Surgical pathology report (de-identified scan), TCGA case TCGA-KS-A4IC, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Of Michigan, specimen TCGA-KS-A4IC-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

BIRTHDATE:

PAGE #:

1

SEX: F

ADM DATE:

PAT TYPE:

OPER DATE:

PROCEDURE: SPHS

Patient with thyroid nodule. Operative Procedure/Tissue Submitted: Total thyroidectomy with possible CND.

PROCEDURE: SPGD

1. "Total thyroid" A small vial of formalin containing a 13.94 gram total thyroid, with the right lobe measuring 4.3 cm tall x 2.5 cm wide x 1.1 cm deep, and a left lobe, 4.2 cm tall x 2.0 cm wide x 1.5 cm deep, and a 1.2 cm wide, 1.7 cm tall x 1.0 cm deep isthmus. The right lobe is inked green, the isthmus inked yellow, the left lobe inked blue. The left lobe has been previously incised for tissue procurement. The specimen is serially sectioned to reveal a 1.1 x 1.1 x 1.0 cm centrally placed encapsulated cystic nodule with focal calcifications and a granular appearance inside the nodule. The nodule does not appear to involve the peripheral margin. Also identified is a 0.3 cm smooth tan nodule, on the superior aspect of the isthmus, lymph node vs. parathyroid. The specimen is submitted as follows: 1A is the superior left lobe.

1B-C is the left lobe nodule in middle of lobe.

1D is the inferior left lobe.

1E is the isthmus.

1F is the right superior lobe.

1G is right mid lobe.

1H is right lower lobe.

2. "Central neck contents" Received in formalin in a small vial containing three pink-tan bits, 0.5 cm each. Specimen submitted entirely in cassette 2A.

PROCEDURE: SPMI

PAPILLARY THYROID CARCINOMA

1CD-0-3

Carcinoma, papillary, thyroid, 8360/3

Site: thyroid, NOS C73.9

h
10/1/12

Size of largest primary tumor: 1.1 x 1.1 x 1.0 cm

Location(s): Left lobe

Capsular Invasion: No

Vascular Invasion: No

Margins: Negative

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

PAGE #: 2

BIRTHDATE:

PAT TYPE:

SEX: F

ADM DATE:

OPER DATE:

Extrathyroidal extension: No

Lymph node metastases: Yes

Extranodal extension: Yes

SIDE	LEVEL	#POSITIVE NODES	#TOTAL NODES
Central Neck Contents	N/A	2	3
Isthmus	N/A	0	1
TOTAL CENTRAL:	—	2	4

PROCEDURE: SPDX

1. Thyroid, total thyroidectomy: Papillary thyroid carcinoma, 1.1 cm. Please see TEMPLATE for details. One lymph node, negative for neoplasm (0/1).

2. Soft tissue, central neck, excision: Metastatic papillary carcinoma within two of three lymph nodes (2/3), with focal extranodal extension.

I, [REDACTED] the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

Source: NCI Genomic Data Commons file 86a39f01-187f-4f22-bcb5-6f3cbcf928d0 (TCGA-KS-A4IC.64802136-E632-4C35-9CE6-C1CC1F7E6022.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).